Somatic mutation profile of tumor specimen C3L-01599-02 (aliquot CPT0087260009) from CPTAC case C3L-01599, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 66.0 years (24,089 days).
Specimen C3L-01599-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28faf03f-3904-4556-a8ac-e37362fefe22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01599-31 (Blood Derived Normal), aliquot CPT0087490002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33e28e4a-6856-40c0-b3d4-d3603166bf1c

The open-access MAF lists 124 somatic variants for this specimen: 94 protein-altering or splice-affecting, 17 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 17, Intron 10, Frame Shift Del 8, Nonsense Mutation 5, Splice Site 4, 3'UTR 3, Translation Start Site 1, In Frame Del 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 103/612 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- BEST1 | c.684C>G p.D228E | Missense Mutation (SNP) | VAF 78/664 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1431752515; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CCND1 | c.856A>G p.T286A | Missense Mutation (SNP) | VAF 6/62 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV57121499, COSV57122110; called by muse, mutect2
- CNGA1 | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 29/200 reads (15%) | catalogued as rs369717052, CM1511726, COSV62057121; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3139C>T p.H1047Y | Missense Mutation (SNP) | VAF 25/199 reads (13%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen benign (0); catalogued as rs121913281, CM126699, COSV55876499, COSV55912376; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 24/322 reads (7%) | hotspot (GDC flag); catalogued as rs786204864, CM142087, HM971504, COSV64288951, COSV64296078, COSV64302138; ClinVar: pathogenic; called by muse, mutect2
- PTEN | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 63/331 reads (19%) | catalogued as rs1455551840, COSV64289209, COSV64297686, COSV64302100; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STAT3 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 60/564 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193922716, CM086668; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARHGAP35 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101351271; called by muse, mutect2, varscan2
- ARID1A | c.4480C>T p.Q1494* | Nonsense Mutation (SNP) | VAF 50/327 reads (15%) | catalogued as rs1553153231; ClinVar: drug response; called by muse, mutect2, varscan2
- CUL2 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV66079059; called by muse, mutect2
- DLGAP2 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 35/335 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1423353722, COSV101423105, COSV70094440; called by muse, mutect2, varscan2
- DMD | c.8601G>T p.E2867D | Missense Mutation (SNP) | VAF 32/370 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV58943565; called by muse, mutect2
- DMGDH | c.1148G>A p.G383E | Missense Mutation (SNP) | VAF 33/302 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1490376179; called by muse, mutect2, varscan2
- DSCAM | c.4670C>T p.A1557V | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs374349326; called by muse, mutect2
- GHR | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 58/438 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs775194712, COSV50117116; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPIHBP1 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 34/324 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.804); catalogued as rs756671297, CM165635, COSV100427391; called by muse, mutect2, varscan2
- GTPBP6 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 50/696 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759901566; called by muse, mutect2
- INAVA | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1451697421; called by muse, mutect2
- KCTD8 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100759261; called by muse, mutect2, varscan2
- KIDINS220 | c.746C>T p.T249M | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.659); catalogued as rs771589853; called by muse, mutect2, varscan2
- KLHL29 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs781228421; called by mutect2, varscan2
- LGR5 | c.2566G>A p.D856N | Missense Mutation (SNP) | VAF 29/266 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1472292248; called by muse, mutect2
- MALT1 | c.1475C>T p.T492M | Missense Mutation (SNP) | VAF 28/237 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769025149, COSV100618825, COSV61936238; called by muse, mutect2, varscan2
- MCAM | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.321); catalogued as rs138068064; called by muse, mutect2, varscan2
- MST1R | c.3913C>T p.R1305C | Missense Mutation (SNP) | VAF 20/231 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777901325, COSV56571823; called by muse, mutect2
- MUSK | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.718); catalogued as rs1473606990; called by muse, mutect2
- MYH13 | c.4223C>T p.T1408M | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.047); catalogued as rs373425936; called by muse, mutect2, varscan2
- OMP | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs782325915, COSV53687241; called by muse, mutect2, varscan2
- PASD1 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761622222, COSV64854816; called by muse, mutect2
- PCDH19 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 31/320 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55260253; called by muse, mutect2, varscan2
- PELI1 | c.97del p.D33Ifs*20 | Frame Shift Del (DEL) | VAF 13/111 reads (12%) | catalogued as COSV62730274; called by mutect2, pindel, varscan2
- PLEKHG1 | c.2735G>A p.R912H | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs149488054; called by muse, mutect2, varscan2
- POTED | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 56/364 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.689); catalogued as rs754919791, COSV55048988; called by muse, mutect2, varscan2
- PPP6R1 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs377467623; called by muse, mutect2
- RAB11FIP5 | c.1894C>T p.R632W | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs752218696, COSV99241822; called by muse, mutect2
- RAB1B | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV104394616; called by muse, mutect2, varscan2
- RPGRIP1L | c.1877A>G p.D626G | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1437729375; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPS6KB2 | c.801G>A p.P267= | Splice Region (SNP) | VAF 12/160 reads (8%) | catalogued as rs1229374921, COSV57051821; called by muse, mutect2
- SAGE1 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1168792762; called by muse, mutect2
- SIN3A | c.3147del p.Y1050Ifs*8 | Frame Shift Del (DEL) | VAF 26/179 reads (15%) | catalogued as COSV64581843; called by mutect2, pindel, varscan2
- SLC22A17 | n.863+1G>A | Splice Site (SNP) | VAF 41/390 reads (11%) | catalogued as rs1230128511, COSV52835203; called by muse, mutect2, varscan2
- SPOP | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 16/279 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV61652768; called by muse, mutect2
- TNNT1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 42/356 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138345373; called by muse, mutect2, varscan2
- TNRC18 | c.8167G>A p.A2723T | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as rs1275096928; called by muse, mutect2, varscan2
- TRIM64C | c.348G>T p.E116D | Missense Mutation (SNP) | VAF 29/349 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.783); catalogued as rs1358910229; called by muse, mutect2
- TTN | c.9929C>T p.T3310I (on ENST00000591111; = p.T3264I on NM_003319.4) | Missense Mutation (SNP) | VAF 60/396 reads (15%) | PolyPhen possibly damaging (0.693); catalogued as rs1433903188; called by muse, varscan2
- WDR90 | c.2889_2895+1del | Frame Shift Del (DEL) | VAF 10/125 reads (8%) | catalogued as rs762096909; called by mutect2, pindel
- WNK3 | c.2137G>A p.V713I | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs782304144; called by muse, mutect2
- YEATS2 | c.313A>G p.M105V | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs753111480, COSV59361279; called by muse, mutect2, varscan2
- ZBTB8OS | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.778); catalogued as rs772562698; called by muse, varscan2
- ZC3H13 | c.2852G>A p.R951Q | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.073); catalogued as rs1383213121, COSV54465179; called by muse, mutect2, varscan2
- ZNF804A | c.2440C>T p.R814* | Nonsense Mutation (SNP) | VAF 35/274 reads (13%) | catalogued as rs772974941, COSV56437401, COSV56474195; called by muse, mutect2, varscan2
- ACSL1 | c.375+1G>A p.X125_splice | Splice Site (SNP) | VAF 18/190 reads (9%) | called by muse, mutect2
- ADGRG4 | c.5360C>T p.T1787I | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.112); called by muse, mutect2
- ANKS1B | c.2728T>C p.Y910H (on ENST00000547776 / NM_152788.4; = p.Y136H on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AP1M1 | c.495G>C p.K165N | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- AP3B1 | c.1795del p.L599* | Frame Shift Del (DEL) | VAF 14/171 reads (8%) | called by mutect2, pindel
- ARID1A | c.1593_1597del p.A532Ifs*89 | Frame Shift Del (DEL) | VAF 50/464 reads (11%) | called by mutect2, pindel
- CARF | c.1694del p.L565Cfs*19 | Frame Shift Del (DEL) | VAF 13/118 reads (11%) | called by mutect2, pindel, varscan2
- CEACAM3 | c.582A>T p.Q194H | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.429); called by muse, mutect2
- CIDEC | c.191A>G p.E64G | Missense Mutation (SNP) | VAF 33/336 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.272); called by muse, mutect2
- E2F4 | c.703C>A p.Q235K | Missense Mutation (SNP) | VAF 45/381 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FBXL6 | c.494C>G p.P165R | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.785); called by muse, mutect2
- IGF2BP3 | c.1339C>A p.P447T | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.712); called by muse, mutect2
- ITGAV | c.2140_2156del p.G714Wfs*25 | Frame Shift Del (DEL) | VAF 17/229 reads (7%) | called by mutect2, pindel
- KPNA6 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 15/224 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2
- MDGA1 | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- MFHAS1 | c.1094C>T p.S365F | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- MROH2B | c.2709G>T p.W903C | Missense Mutation (SNP) | VAF 23/264 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYO3A | c.1662-2A>T p.X554_splice | Splice Site (SNP) | VAF 34/344 reads (10%) | called by muse, mutect2
- NDST4 | c.172C>A p.L58I | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.013); called by muse, mutect2
- NEXMIF | c.386C>A p.A129E | Missense Mutation (SNP) | VAF 40/303 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- NF2 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 65/681 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.571); called by muse, mutect2
- PICALM | c.329dup p.L110Ffs*3 | Frame Shift Ins (INS) | VAF 16/194 reads (8%) | called by mutect2, pindel
- PIK3C2B | c.1274T>C p.V425A | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.471); called by muse, mutect2
- PIK3R1 | c.1705_1737del p.D569_Q579del (on ENST00000521381 / NM_181523.3; = p.D299_Q309del on NM_181504.4) | In Frame Del (DEL) | VAF 16/196 reads (8%) | called by mutect2, pindel
- PRUNE2 | c.8724C>A p.H2908Q | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSD3 | c.21+2T>A p.X7_splice | Splice Site (SNP) | VAF 25/230 reads (11%) | called by muse, mutect2, varscan2
- SIGLEC15 | c.643C>G p.R215G | Missense Mutation (SNP) | VAF 32/305 reads (10%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC25A4 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 25/400 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.554); called by muse, mutect2
- SLX4 | c.3287G>A p.G1096E | Missense Mutation (SNP) | VAF 69/576 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- SNAPIN | c.171A>T p.Q57H | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- TANC1 | c.2144A>G p.Q715R | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TBX1 | c.880G>T p.G294C | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TBX5 | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 53/674 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2
- THEM5 | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TLE1 | c.1603_1613del p.S535Afs*85 | Frame Shift Del (DEL) | VAF 22/169 reads (13%) | called by mutect2, pindel
- TNR | c.3401A>G p.H1134R | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- TRAPPC8 | c.2971G>A p.V991M | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.014); called by muse, mutect2
- UGT3A1 | c.648C>A p.D216E | Missense Mutation (SNP) | VAF 31/410 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.014); called by muse, mutect2
- WNT8A | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFP69 | c.841A>C p.K281Q | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- ZNF518B | c.1112G>T p.C371F | Missense Mutation (SNP) | VAF 17/304 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.086); called by muse, mutect2
- ADAMTS8 | c.2202G>A p.A734= | Silent (SNP) | VAF 26/296 reads (9%) | catalogued as rs764701055, COSV99961309; called by muse, mutect2
- B3GALT6 | c.921C>T p.R307= | Silent (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- EXPH5 | c.2262C>T p.N754= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as rs775406227, COSV56199053; called by muse, mutect2, varscan2
- FAM86B1 | c.426C>T p.C142= | Silent (SNP) | VAF 55/575 reads (10%) | catalogued as rs777084907; called by muse, mutect2, varscan2
- FN1 | c.1005C>T p.C335= | Silent (SNP) | VAF 54/454 reads (12%) | called by muse, mutect2, varscan2
- INPP5D | c.2202C>G p.L734= (on ENST00000445964 / NM_001017915.3; = p.L733= on NM_005541.5) | Silent (SNP) | VAF 14/204 reads (7%) | called by muse, mutect2
- KCNH1 | c.2388G>A p.T796= (on ENST00000271751 / NM_172362.3; = p.T769= on NM_002238.4) | Silent (SNP) | VAF 22/272 reads (8%) | catalogued as rs138875472; called by muse, mutect2
- KLHDC7A | c.1692G>A p.P564= | Silent (SNP) | VAF 18/146 reads (12%) | called by muse, mutect2, varscan2
- MIEF1 | c.246G>T p.L82= | Silent (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- MYPN | c.3564C>T p.P1188= | Silent (SNP) | VAF 69/459 reads (15%) | catalogued as rs768400415; called by muse, mutect2, varscan2
- PCDHA10 | c.1716G>A p.A572= | Silent (SNP) | VAF 23/430 reads (5%) | catalogued as rs552891884; called by muse, mutect2
- PCDHA2 | c.1365C>T p.F455= | Silent (SNP) | VAF 35/431 reads (8%) | catalogued as COSV65370460; called by muse, mutect2
- PDE4A | c.1143C>T p.C381= (on ENST00000380702 / NM_001111307.2; = p.C142= on NM_006202.3) | Silent (SNP) | VAF 22/167 reads (13%) | catalogued as rs769665964, COSV53362124; called by muse, mutect2, varscan2
- PPM1H | c.879C>A p.I293= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as rs1213409749; called by muse, mutect2
- RYR1 | c.9519C>T p.Y3173= | Silent (SNP) | VAF 54/500 reads (11%) | catalogued as rs138815601; called by muse, mutect2, varscan2
- SRCIN1 | c.2091C>T p.D697= (on ENST00000621492; = p.D663= on NM_025248.3) | Silent (SNP) | VAF 17/179 reads (9%) | called by muse, mutect2
- TBC1D8 | c.549C>T p.N183= | Silent (SNP) | VAF 20/164 reads (12%) | called by muse, mutect2, varscan2
- ABCC3 | c.45+293G>T | Intron (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- ANO9 | c.771+60G>A | Intron (SNP) | VAF 35/202 reads (17%) | catalogued as rs961437088; called by muse, mutect2, varscan2
- MGAT4B | c.97+47G>C | Intron (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
- MOCS1 | c.*655G>A | 3'UTR (SNP) | VAF 42/400 reads (11%) | catalogued as rs892789300; called by muse, mutect2, varscan2
- PAPOLA | c.2005-9T>A | Intron (SNP) | VAF 14/126 reads (11%) | catalogued as rs201275170, COSV53478542, COSV53478897; called by muse, mutect2, varscan2
- RAD51D | c.345+42G>T | Intron (SNP) | VAF 50/314 reads (16%) | called by muse, mutect2, varscan2
- RASSF6 | c.63-4071A>G | Intron (SNP) | VAF 13/286 reads (5%) | called by muse, mutect2
- RPL7A | c.3+22G>A | Intron (SNP) | VAF 22/252 reads (9%) | called by muse, mutect2
- SLC28A1 | c.461+372C>T | Intron (SNP) | VAF 24/211 reads (11%) | catalogued as rs375991676; called by muse, mutect2
- SLC9A3 | c.*573G>T | 3'UTR (SNP) | VAF 14/153 reads (9%) | called by muse, mutect2
- SYT14 | c.*44C>T | 3'UTR (SNP) | VAF 84/624 reads (13%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+2963C>T | Intron (SNP) | VAF 20/119 reads (17%) | called by muse, mutect2, varscan2
- ZNF384 | c.686+889A>G | Intron (SNP) | VAF 19/141 reads (13%) | called by muse, mutect2, varscan2
